CCDI case PBBITE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/851c7641-f572-430d-9b19-50f057d94799

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Brain stem; Age at diagnosis: 2.4 years (860 days).

Biospecimens (3 samples)
- Sample 0DAZOY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAZP5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DAZP6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
